Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A2J0, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A2J0-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

ICD-0-3

dedifferentiated liposarcoma

8858/3

Site: retroperitoneum C48.0

hw 7/24/11

....

Clinical Diagnosis & History:

Palpable mass. CT demonstrated a 15 x 11.5 cm retroperitoneal mass adjacent to the left kidney. Core biopsy showed dedifferentiated liposarcoma.

Specimens Submitted:

1: SP: Retroperitoneal sarcoma, left kidney, spleen, adrenal left colon and distal pancreas

DIAGNOSIS:

- 1) KIDNEY, ADRENAL GLAND AND COLON, LEFT, SPLEEN, AND DISTAL PANCREAS, RETROPERITONEAL MASS, EXTENSIVE RESECTION:
- DEDIFFERENTIATED LIPOSARCOMA, HIGH GRADE.
- WELL DIFFERENTIATED LIPOSARCOMA (LIPOMA-LIKE) INVOLVES PANCREAS (INCLUDING DISTAL PANCREATIC MARGIN), SURROUNDS BUT DOES NOT INVADE ADRENAL GLAND, AND INVOLVES COLONIC SEROSA; HIGH GRADE, NONLIPOGENIC ELEMENTS INVADE RENAL CORTEX.
- TUMOR MEASURES 25.0 CM IN GREATEST DIMENSION AND IS ABOUT 20% NECROTIC.
- UNDESIGNATED SOFT TISSUE MARGINS ARE INVOLVED BY WELL DIFFERENTIATED LIPOSARCOMA AND HIGH GRADE ELEMENTS; COLONIC MARGINS ARE FREE OF TUMOR.
- HISTOLOGICALLY UNREMARKABLE SPLEEN.
- IMMUNOSTAINS PERFORMED ON A BLOCK WITH EPITHELIOID FEATURES ARE POSITIVE FOR CD10, NEGATIVE FOR AE1/AE3, CAM 5.2, EMA, AND RCC.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

MD,

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	AE1:AE3	
	CAM 5.2	
	RCC	
	CD10	
	EMA	
	NEG CONT	

** Continued on next page **

[page 2 of 3]
IMM RECUT

Gross Description:

M.D.

1) The specimen is received fresh, labeled "Retroperitoneal sarcoma, left kidney, spleen adrenal, left colon and distal pancreas". It consists of a large multilobulated mass surrounded by a thick fibrous capsule that measures 25.0 x 18.5 x 14.0 cm with attached spleen, omentum, portion of pancreas and a portion of colon. The attached portion of colon measures 25.0 cm in length and up to 7.0 cm in circumference. The mucosa is intact. The spleen measures 12.0 x 11.0 x 4.0 cm and weighs 172 gm. The capsule is smooth and the cut surfaces are unremarkable. The portion of distal pancreas measures 7.0 x 4.5 x 2.0 cm. The omentum measures 20.0 x 15.0 x 3.5 cm. Sections through the mass reveal a kidney that measures 12.0 x 5.6 x 4.5 cm which abuts the mass. Ureter cannot be identified because of distortion by the tumor. An adrenal gland is also identified measuring 5.0 x 2.0 x 0.8 cm and appears away from the tumor. The tumor ranges in color from light tan to brown and in consistency from firm and gritty to soft and gelatinous. Portions of the specimen are given for TPS. A photograph is taken and representative sections are submitted.

Summary of sections:

PM pancreatic margin
SP spleen
O omentum
CM colonic margins
AG adrenal gland
P pancreas.
CWT colon with tumor
KWT kidney with tumor
T tumor

Summary of Sections:

Part 1: SP: Retroperitoneal sarcoma, left kidney, spleen, adrenal left colon and distal pancreas

Block	Sect.	Site	PCs
1		AG	1
1		CM	1
1		CWT	1
2		KWT	2
1		O	1
1		P	1
1		PM	1
1		SP	1
25		T	25

** Continued on next page **

[page 3 of 3]
Intraoperative Consultation:

** End of Report **

Source: NCI Genomic Data Commons file 53801cc5-0720-400b-9a7e-d557c13f6210 (TCGA-DX-A2J0.4B656153-FCF6-4C60-AD3A-3AD4715CC063.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).